Somatic mutation profile of tumor specimen TCGA-B3-3926-01A (aliquot TCGA-B3-3926-01A-01D-1252-08) from TCGA case TCGA-B3-3926, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 59.9 years (21,876 days).
Specimen TCGA-B3-3926-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1eb9d1d7-6894-49eb-94ec-3468fb5c59b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B3-3926-11A (Solid Tissue Normal), aliquot TCGA-B3-3926-11A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e06e6482-3864-42a9-9181-77376b4ac423

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBAK | c.2140C>T p.L714F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV62330764; called by muse, mutect2, varscan2
- THBD | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1226992689, COSV101001932; called by muse, mutect2
- UBA52 | c.268A>T p.N90Y | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV70615262; called by muse, mutect2, varscan2
- ALK | c.3758G>C p.R1253T | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPDR1 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRC2 | c.3334+2T>C p.X1112_splice | Splice Site (SNP) | VAF 14/72 reads (19%) | called by muse, varscan2
- PLXND1 | c.4302G>T p.K1434N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SAV1 | c.303_310del p.R101Sfs*5 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- SLC2A2 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2
